Somatic mutation profile of tumor specimen MP2PRT-PAVGER-TMP1-A (aliquot MP2PRT-PAVGER-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGER, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (815 days).
Specimen MP2PRT-PAVGER-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3426662f-cfac-42d7-8590-98872060b905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGER-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGER-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6752b216-91e6-4ac9-adc0-acdfe6d8029b

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 118/467 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.1889C>T p.T630I (on ENST00000611781; = p.T574I on NM_052997.2) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.84); catalogued as rs764425571; called by muse, mutect2
- CACNA1B | c.6551G>A p.R2184H | Missense Mutation (SNP) | VAF 160/789 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756380021, COSV99496276; called by muse, mutect2, varscan2
- IL18R1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs773036985, COSV52126307, COSV99295001; called by muse, mutect2, varscan2
- KCNH4 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 94/390 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292596032; called by muse, mutect2, varscan2
- SPOCK3 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 66/399 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs965665668; called by muse, mutect2, varscan2
- PSG2 | c.792C>A p.N264K | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RC3H1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RND3 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SYNJ1 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- C2orf76 | c.75G>A p.V25= | Silent (SNP) | VAF 111/374 reads (30%) | called by muse, mutect2, varscan2
- VPS50 | c.93C>T p.V31= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as COSV52493883; called by muse, mutect2, varscan2
- KCNC1 | chr11:17779496 G>A | 3'Flank (SNP) | VAF 101/387 reads (26%) | catalogued as rs763202742; called by muse, mutect2, varscan2
- LSP1P4 | n.146T>A | RNA (SNP) | VAF 24/178 reads (13%) | called by mutect2, varscan2
